Somatic mutation profile of tumor specimen SM-JU34Z (aliquot 7316UP-961) from CPTAC case C207624, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen SM-JU34Z: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b73b4f71-d321-4af9-9e99-01e25471385e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105207 (Blood Derived Normal), aliquot 7316UP-603-1105207; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1b465e8-a743-4929-a461-1590db19fca8

The open-access MAF lists 42 somatic variants for this specimen: 24 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 15, Nonsense Mutation 3, Intron 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DBH | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs766166337, COSV55039535; called by muse, mutect2
- DMWD | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54289226; called by muse, mutect2
- FNDC1 | c.5485G>T p.E1829* | Nonsense Mutation (SNP) | VAF 27/245 reads (11%) | catalogued as COSV51938765; called by muse, mutect2, varscan2
- HABP2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs776334292, COSV63636120; called by muse, mutect2
- HR | c.3349G>A p.V1117M | Missense Mutation (SNP) | VAF 59/571 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747696916; called by muse, mutect2, varscan2
- MYEF2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99981562; called by muse, mutect2
- NFATC2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs1568726068, COSV65353091; called by muse, mutect2
- PAX1 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV68272913; called by muse, mutect2, varscan2
- PKD1 | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 71/806 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs376991027; called by muse, mutect2
- SP3 | c.1778A>G p.K593R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.235); catalogued as rs781269537; called by muse, mutect2, varscan2
- SRD5A2 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as COSV51873520; called by muse, mutect2
- STAG2 | c.2673+1G>A p.X891_splice | Splice Site (SNP) | VAF 6/57 reads (11%) | catalogued as COSV54352346, COSV54366275; called by muse, mutect2
- TACR3 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 52/600 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs202051644; called by muse, mutect2
- WDFY4 | c.2996C>T p.A999V | Missense Mutation (SNP) | VAF 20/373 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as rs568244681, COSV57444519; called by muse, mutect2
- ADGRA3 | c.1216T>C p.W406R | Missense Mutation (SNP) | VAF 42/629 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGA | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 46/662 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.046); called by muse, mutect2
- HMCN1 | c.15505G>T p.G5169* | Nonsense Mutation (SNP) | VAF 44/618 reads (7%) | called by muse, mutect2
- IGFLR1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2
- MUC4 | c.9853G>T p.D3285Y | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2
- MYO10 | c.5019C>G p.Y1673* | Nonsense Mutation (SNP) | VAF 32/296 reads (11%) | called by muse, mutect2, varscan2
- PRDM9 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 70/840 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.725); called by muse, mutect2
- SLC35A2 | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.115); called by muse, mutect2
- SRGAP2 | c.857G>T p.S286I (on ENST00000624873 / NM_001170637.4; = p.S287I on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- STXBP1 | c.1548-1G>A p.X516_splice | Splice Site (SNP) | VAF 42/494 reads (9%) | called by muse, mutect2
- ARMCX2 | c.639G>A p.S213= | Silent (SNP) | VAF 42/473 reads (9%) | catalogued as rs200974747; called by muse, mutect2
- CHRNA4 | c.46C>T p.L16= | Silent (SNP) | VAF 46/536 reads (9%) | catalogued as COSV64717727; called by muse, mutect2
- COL6A1 | c.615G>A p.T205= | Silent (SNP) | VAF 72/815 reads (9%) | catalogued as rs192125814; ClinVar: likely benign; called by muse, mutect2
- DCAF12L2 | c.849C>T p.D283= | Silent (SNP) | VAF 20/193 reads (10%) | catalogued as rs1054703704, COSV63583731; called by muse, mutect2, varscan2
- FAM135B | c.2742T>C p.G914= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- ILDR1 | c.222C>T p.Y74= | Silent (SNP) | VAF 18/262 reads (7%) | catalogued as rs1260195067; called by muse, mutect2
- INPP5D | c.2382T>C p.P794= (on ENST00000445964 / NM_001017915.3; = p.P793= on NM_005541.5) | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2
- MMGT1 | c.267C>A p.S89= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- OR4K2 | c.228C>T p.F76= | Silent (SNP) | VAF 24/180 reads (13%) | catalogued as rs370258306, COSV53848469; called by muse, mutect2, varscan2
- OSCP1 | c.15G>A p.T5= | Silent (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- PCDHB1 | c.1329C>G p.S443= | Silent (SNP) | VAF 21/301 reads (7%) | catalogued as COSV60629356; called by muse, mutect2
- RECQL4 | c.2286G>A p.Q762= | Silent (SNP) | VAF 52/638 reads (8%) | catalogued as COSV99468277; called by muse, mutect2
- WWP2 | c.2382G>A p.L794= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- YWHAB | c.639T>C p.Y213= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as rs755545276; called by muse, mutect2, varscan2
- ZNF469 | c.10575G>A p.P3525= (on ENST00000437464; = p.P3553= on NM_001367624.2) | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs957291420; called by muse, mutect2, varscan2
- NR5A2 | c.1110+8717G>T | Intron (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.6318C>T | RNA (SNP) | VAF 10/112 reads (9%) | catalogued as COSV50487378; called by muse, mutect2
- TTN | c.32876-34G>A | Intron (SNP) | VAF 26/312 reads (8%) | catalogued as rs527456592, COSV59897810; called by muse, mutect2
